Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6455, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6455-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report			
			STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Stomach Tumor size: 12 x 7 x 2 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Lesser and greater omentum Lymph nodes: 2/19 positive for metastasis (Intraabdominal 2/19) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 1ad08277-d857-41a0-bae6-a4ce8fb56877 (TCGA-BR-6455.C545EABB-6BEF-4439-8A94-F1B382E800D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).